Somatic mutation profile of tumor specimen TCGA-BQ-5877-01A (aliquot TCGA-BQ-5877-01A-11D-1589-08) from TCGA case TCGA-BQ-5877, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.5 years (22,095 days).
Specimen TCGA-BQ-5877-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c02d4d1e-d295-4525-bfdb-d04600f66fea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5877-11A (Solid Tissue Normal), aliquot TCGA-BQ-5877-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fddbdfe8-1177-4526-8277-0357faacd77a

The open-access MAF lists 82 somatic variants for this specimen: 68 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Frame Shift Del 8, Nonsense Mutation 6, Frame Shift Ins 5, In Frame Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRD1 | c.86G>C p.R29T | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.023); catalogued as COSV55456751; called by muse, mutect2, varscan2
- AK7 | c.1234A>T p.I412F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV50881921; called by muse, mutect2, varscan2
- AMD1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 116/354 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs1463233722, COSV64387596; called by muse, mutect2, varscan2
- ANKS4B | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs765325045, COSV61140083; called by muse, mutect2, varscan2
- ARHGEF28 | c.2466T>A p.D822E | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV55269274; called by muse, mutect2, varscan2
- BAP1 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV56240482; called by muse, mutect2, varscan2
- BCAN | c.2557C>A p.L853M | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); catalogued as COSV61259540; called by muse, mutect2, varscan2
- CABIN1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs745614916, COSV54080475; called by muse, mutect2, varscan2
- CAPN3 | c.1199C>G p.S400C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV58826144; called by muse, mutect2, varscan2
- CCDC80 | c.2657T>A p.M886K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52819772; called by muse, mutect2, varscan2
- CENPA | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 147/402 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV51983429; called by muse, mutect2, varscan2
- CFAP43 | c.2050C>A p.H684N | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV53379311, COSV53381118; called by muse, mutect2, varscan2
- CFAP70 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 59/177 reads (33%) | catalogued as COSV60286740; called by muse, mutect2, varscan2
- CFAP70 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.368); catalogued as rs964993020, COSV60286745; called by muse, mutect2, varscan2
- CLCN2 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.447); catalogued as rs199539697, COSV55602937; called by muse, mutect2, varscan2
- DCC | c.3983G>T p.S1328I | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV71440491; called by muse, mutect2, varscan2
- DSP | c.693T>A p.Y231* | Nonsense Mutation (SNP) | VAF 69/102 reads (68%) | catalogued as COSV65795792; called by muse, mutect2, varscan2
- EBF2 | c.577T>G p.C193G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68780512; called by muse, mutect2, varscan2
- EXOC8 | c.797A>T p.N266I | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50479737; called by muse, mutect2, varscan2
- FAT1 | c.6494C>T p.S2165L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV71675698; called by mutect2, varscan2
- FAT2 | c.2330C>G p.P777R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV55829048; called by muse, mutect2, varscan2
- FBXO33 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV53235946; called by muse, mutect2, varscan2
- HCRTR2 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV63798997; called by muse, mutect2, varscan2
- IGHM | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.737); catalogued as rs369232248; called by muse, mutect2
- IGKV1-5 | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs11546105; called by muse, mutect2, varscan2
- JPH4 | c.1736G>C p.G579A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58115175, COSV58115607; called by muse, mutect2, varscan2
- LSP1 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.056); catalogued as rs370626038, COSV61137383; called by muse, mutect2, varscan2
- MAP1B | c.365C>A p.T122N | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57106058; called by muse, mutect2, varscan2
- MCF2L2 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 36/110 reads (33%) | catalogued as COSV61061097; called by muse, mutect2, varscan2
- MTFR2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150447506; called by muse, mutect2, varscan2
- MYH4 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as rs774524623, COSV55124896; called by muse, mutect2, varscan2
- MYO15A | c.4700T>G p.L1567R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52765592; called by muse, mutect2, varscan2
- NBAS | c.2995A>C p.I999L | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV55737191; called by muse, mutect2, varscan2
- NF2 | c.511A>T p.K171* | Nonsense Mutation (SNP) | VAF 69/138 reads (50%) | catalogued as COSV58530586; called by muse, mutect2, varscan2
- NUMB | c.772C>T p.P258S (on ENST00000355058; = p.P247S on NM_003744.5) | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV61832140; called by muse, mutect2, varscan2
- NUTM2D | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV67746960; called by muse, mutect2, varscan2
- ORC2 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 48/157 reads (31%) | catalogued as COSV52241487; called by muse, mutect2, varscan2
- PLD6 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.094); catalogued as rs139543758, COSV58634141; called by muse, mutect2, varscan2
- PSME4 | c.3538G>C p.V1180L | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV66367463; called by muse, mutect2, varscan2
- SALL1 | c.1364C>G p.A455G | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs756599740, COSV51764349, COSV99179263; called by muse, mutect2, varscan2
- SLC44A2 | c.948G>C p.L316F | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV59838913; called by muse, mutect2, varscan2
- SLC5A6 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60161401; called by muse, mutect2, varscan2
- SNCAIP | c.2542T>G p.S848A | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.058); catalogued as COSV54421007; called by muse, mutect2, varscan2
- SPAG7 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.239); catalogued as COSV52779439; called by muse, mutect2, varscan2
- SPHK1 | c.757C>G p.P253A (on ENST00000392496 / NM_001355139.2; = p.P267A on NM_021972.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV60067588; called by muse, mutect2, varscan2
- SPINK4 | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV65688290; called by muse, mutect2, varscan2
- TG | c.1232del p.T411Rfs*68 | Frame Shift Del (DEL) | VAF 101/361 reads (28%) | catalogued as COSV55078330; called by mutect2, pindel, varscan2
- TNKS1BP1 | c.1930C>A p.L644M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV64102534; called by muse, mutect2, varscan2
- TTC27 | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV58656359; called by muse, mutect2, varscan2
- USP32 | c.602A>C p.K201T | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56277144; called by muse, mutect2, varscan2
- ZFP82 | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67566290, COSV67566712; called by muse, mutect2, varscan2
- ZNF341 | c.1475A>C p.E492A (on ENST00000375200 / NM_001282935.1; = p.E485A on NM_032819.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV100677930, COSV61011150; called by muse, mutect2, varscan2
- ZNF613 | c.507T>A p.H169Q (on ENST00000293471 / NM_001031721.4; = p.H133Q on NM_024840.4) | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV53273905; called by muse, mutect2, varscan2
- ZNF823 | c.1118C>G p.S373W (on ENST00000341191 / NM_001297610.2; = p.S329W on NM_017507.2) | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57876177; called by muse, mutect2, varscan2
- CADM2 | c.1107_1108insT p.I370Yfs*27 (on ENST00000407528 / NM_001167674.2; = p.I372Yfs*27 on NM_153184.4) | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- CPXM1 | c.1978dup p.Y660Lfs*31 | Frame Shift Ins (INS) | VAF 25/72 reads (35%) | called by mutect2, pindel, varscan2
- EBF3 | c.487del p.R163Gfs*19 | Frame Shift Del (DEL) | VAF 41/171 reads (24%) | called by mutect2, pindel, varscan2
- FAT1 | c.6495del p.A2166Rfs*10 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | called by mutect2, varscan2
- GRAMD1A | c.251_252insAC p.T85Pfs*65 | Frame Shift Ins (INS) | VAF 41/145 reads (28%) | called by mutect2, pindel, varscan2
- IRX5 | c.652_653del p.A218Rfs*4 | Frame Shift Del (DEL) | VAF 57/216 reads (26%) | called by mutect2, pindel, varscan2
- KIF21B | c.651_652del p.Q217Hfs*30 | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | called by mutect2, pindel, varscan2
- MEFV | c.1363dup p.T455Nfs*2 | Frame Shift Ins (INS) | VAF 39/131 reads (30%) | called by mutect2, pindel, varscan2
- NFATC2 | c.2281_2295del p.S761_Y765del | In Frame Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- NYNRIN | c.4053del p.Y1352Mfs*88 | Frame Shift Del (DEL) | VAF 40/143 reads (28%) | called by mutect2, pindel, varscan2
- PPM1F | c.832del p.I278Ffs*9 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | called by mutect2, pindel, varscan2
- SETD2 | c.4369_4375del p.P1457Dfs*24 | Frame Shift Del (DEL) | VAF 43/88 reads (49%) | called by mutect2, pindel, varscan2
- THUMPD2 | c.934dup p.I312Nfs*7 | Frame Shift Ins (INS) | VAF 29/98 reads (30%) | called by mutect2, pindel, varscan2
- XKR4 | c.457_459del p.V153del | In Frame Del (DEL) | VAF 16/68 reads (24%) | called by pindel, varscan2
- ABCA13 | c.1293G>A p.L431= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV70033566; called by muse, mutect2, varscan2
- ATP6V0E1 | c.81C>T p.F27= | Silent (SNP) | VAF 84/238 reads (35%) | catalogued as rs761537915, COSV54186106; called by muse, mutect2, varscan2
- BTBD2 | c.1368G>C p.P456= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs946568000, COSV55310572; called by muse, mutect2, varscan2
- CILP | c.2482C>T p.L828= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV56027734; called by muse, mutect2, varscan2
- CPT1C | c.171C>A p.A57= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV54922076; called by muse, mutect2, varscan2
- DUOX1 | c.3450G>C p.V1150= | Silent (SNP) | VAF 61/178 reads (34%) | catalogued as COSV58486304; called by muse, mutect2, varscan2
- HMCN1 | c.10740A>G p.G3580= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs756468241, COSV54939748; called by muse, mutect2, varscan2
- KAT2B | c.2055C>T p.Y685= | Silent (SNP) | VAF 62/129 reads (48%) | catalogued as COSV55434372; called by muse, mutect2, varscan2
- NSF | c.1872G>A p.Q624= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV56576614, COSV99834077; called by muse, mutect2, varscan2
- PCDH15 | c.3708C>T p.A1236= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs374185988; called by muse, mutect2, varscan2
- RANBP2 | c.8409T>C p.I2803= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs1324047777, COSV51708435; called by muse, mutect2, varscan2
- SLC6A2 | c.537C>T p.T179= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV54923141; called by muse, mutect2, varscan2
- SRRM2 | c.6930T>C p.S2310= | Silent (SNP) | VAF 131/452 reads (29%) | catalogued as COSV51941831; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503841 del ATA | 5'Flank (DEL) | VAF 10/33 reads (30%) | catalogued as rs747696623; called by pindel, varscan2
